Somatic mutation profile of tumor specimen TCGA-62-8394-01A (aliquot TCGA-62-8394-01A-11D-2323-08) from TCGA case TCGA-62-8394, project TCGA-LUAD (Lung Adenocarcinoma). Sex at birth: female; Vital status: Dead; Primary diagnosis: Adenocarcinoma with mixed subtypes; Tissue or organ of origin: Lower lobe, lung; AJCC pathologic stage: Stage IIIB; Age at diagnosis: 65.0 years (23,758 days).
Specimen TCGA-62-8394-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 5623afdf-6852-4592-9a22-a36ac4319bb9.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen TCGA-62-8394-10A (Blood Derived Normal), aliquot TCGA-62-8394-10A-01D-2323-08; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/06c8f74d-21ff-43ff-b921-a364f8010b42

The open-access MAF lists 138 somatic variants for this specimen: 98 protein-altering or splice-affecting, 34 silent, 6 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 90, Silent 34, Nonsense Mutation 6, Intron 3, RNA 2, Splice Site 1, Frame Shift Del 1, 5'Flank 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- EGFR | c.2573T>G p.L858R | Missense Mutation (SNP) | VAF 87/207 reads (42%) | hotspot (GDC flag); SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs121434568, COSV51765161, COSV51854030; ClinVar: likely pathogenic / drug response / pathogenic; called by muse, mutect2, varscan2
- ABLIM3 | c.898G>C p.D300H | Missense Mutation (SNP) | VAF 14/129 reads (11%) | SIFT deleterious (0.04); PolyPhen benign (0.017); catalogued as COSV100448523; called by muse, mutect2, varscan2
- ADGRG4 | c.7345C>T p.Q2449* | Nonsense Mutation (SNP) | VAF 9/111 reads (8%) | catalogued as COSV99795763; called by muse, mutect2
- ALDH1A2 | c.209A>G p.Q70R | Missense Mutation (SNP) | VAF 18/95 reads (19%) | SIFT deleterious (0.03); PolyPhen benign (0.349); catalogued as COSV99990825; called by muse, mutect2, varscan2
- ATP6AP1 | c.845G>T p.W282L | Missense Mutation (SNP) | VAF 29/246 reads (12%) | SIFT tolerated (0.23); PolyPhen benign (0.003); catalogued as COSV100870698; called by muse, mutect2, varscan2
- BCR | c.1471G>C p.D491H | Missense Mutation (SNP) | VAF 6/86 reads (7%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.971); catalogued as COSV100006622; called by muse, mutect2
- CD177 | c.253C>A p.R85S | Missense Mutation (SNP) | VAF 7/89 reads (8%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.748); catalogued as rs759856388, COSV100945979; called by muse, mutect2
- CDC20B | c.786T>A p.N262K | Missense Mutation (SNP) | VAF 19/97 reads (20%) | SIFT tolerated (0.45); PolyPhen benign (0.038); catalogued as rs77495563, COSV99697005; called by muse, mutect2, varscan2
- CDH13 | c.1569G>T p.W523C | Missense Mutation (SNP) | VAF 40/220 reads (18%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV99226973; called by muse, mutect2, varscan2
- CDH24 | c.1316G>A p.R439H | Missense Mutation (SNP) | VAF 13/97 reads (13%) | SIFT deleterious (0.01); PolyPhen probably damaging (1); catalogued as rs750499050, COSV57460536; called by muse, mutect2, varscan2
- CDHR1 | c.263G>A p.G88E | Missense Mutation (SNP) | VAF 6/141 reads (4%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV100258978; called by muse, mutect2
- CDK5 | c.127G>A p.G43S | Missense Mutation (SNP) | VAF 18/77 reads (23%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV99877031; called by mutect2, varscan2
- CELA3B | c.421C>G p.L141V | Missense Mutation (SNP) | VAF 10/146 reads (7%) | SIFT tolerated (0.51); PolyPhen benign (0.003); catalogued as COSV100448787; called by muse, mutect2
- CHD8 | c.1070C>T p.P357L (on ENST00000646647 / NM_001170629.2; = p.P78L on NM_020920.4) | Missense Mutation (SNP) | VAF 16/242 reads (7%) | SIFT tolerated, low confidence (0.26); PolyPhen benign (0); catalogued as COSV101303152; called by muse, mutect2
- CRB1 | c.160T>C p.C54R | Missense Mutation (SNP) | VAF 12/71 reads (17%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); catalogued as COSV100959000; called by muse, mutect2, varscan2
- CTNND2 | c.2282T>C p.V761A | Missense Mutation (SNP) | VAF 10/282 reads (4%) | SIFT deleterious (0); PolyPhen benign (0.003); catalogued as COSV100477714; called by muse, mutect2
- DARS2 | c.332C>T p.P111L | Missense Mutation (SNP) | VAF 12/160 reads (8%) | SIFT deleterious (0); PolyPhen possibly damaging (0.572); catalogued as COSV99508767; called by muse, mutect2
- DDB1 | c.1732C>T p.H578Y | Missense Mutation (SNP) | VAF 27/120 reads (23%) | SIFT tolerated (1); PolyPhen benign (0.012); catalogued as rs1046777534, COSV100074648; called by muse, mutect2, varscan2
- DDX17 | c.1679G>A p.G560D | Missense Mutation (SNP) | VAF 22/110 reads (20%) | SIFT deleterious (0.05); PolyPhen benign (0.142); catalogued as COSV99318253; called by muse, mutect2, varscan2
- DNAH2 | c.3542C>G p.S1181C | Missense Mutation (SNP) | VAF 10/66 reads (15%) | SIFT deleterious (0.05); PolyPhen benign (0.195); catalogued as COSV101209402; called by muse, mutect2, varscan2
- ESX1 | c.530A>T p.N177I | Missense Mutation (SNP) | VAF 36/412 reads (9%) | SIFT deleterious (0); PolyPhen probably damaging (0.944); catalogued as COSV101006470; called by muse, mutect2
- FBLN7 | c.1191C>G p.I397M | Missense Mutation (SNP) | VAF 18/151 reads (12%) | SIFT tolerated (0.15); PolyPhen possibly damaging (0.779); catalogued as COSV99734883; called by muse, mutect2, varscan2
- FBXO31 | c.637C>A p.P213T | Missense Mutation (SNP) | VAF 5/16 reads (31%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.997); catalogued as rs1410552676, COSV100291448; called by muse, mutect2, varscan2
- FOXG1 | c.1346C>T p.S449L | Missense Mutation (SNP) | VAF 10/124 reads (8%) | SIFT deleterious, low confidence (0.05); PolyPhen benign (0.122); catalogued as COSV57395888; called by muse, mutect2
- FOXH1 | c.821G>T p.W274L | Missense Mutation (SNP) | VAF 15/150 reads (10%) | SIFT tolerated (0.1); PolyPhen benign (0.041); catalogued as rs1417452589, COSV100023710; called by muse, mutect2, varscan2
- FOXN1 | c.136T>G p.F46V | Missense Mutation (SNP) | VAF 40/207 reads (19%) | SIFT deleterious, low confidence (0); PolyPhen possibly damaging (0.508); catalogued as rs771191077, COSV99881345; called by muse, mutect2, varscan2
- GPR183 | c.702G>C p.E234D | Missense Mutation (SNP) | VAF 21/233 reads (9%) | SIFT tolerated (0.47); PolyPhen benign (0.01); catalogued as COSV100854301; called by muse, mutect2
- GPRASP2 | c.751G>C p.E251Q | Missense Mutation (SNP) | VAF 10/302 reads (3%) | SIFT deleterious (0.01); PolyPhen benign (0.114); catalogued as COSV100176791; called by muse, mutect2
- GRM5 | c.2388C>A p.N796K | Missense Mutation (SNP) | VAF 27/206 reads (13%) | SIFT tolerated (0.05); PolyPhen probably damaging (0.925); catalogued as COSV100552435; called by muse, mutect2, varscan2
- GUCA1A | c.358C>T p.R120C | Missense Mutation (SNP) | VAF 89/443 reads (20%) | SIFT deleterious (0); PolyPhen probably damaging (0.953); catalogued as COSV50005432; called by muse, mutect2, varscan2
- IBA57 | c.455A>G p.E152G | Missense Mutation (SNP) | VAF 8/28 reads (29%) | SIFT tolerated (0.15); PolyPhen benign (0.326); catalogued as COSV100812780; called by muse, mutect2, varscan2
- IGF2R | c.957C>G p.H319Q | Missense Mutation (SNP) | VAF 17/137 reads (12%) | SIFT tolerated (0.06); PolyPhen possibly damaging (0.66); catalogued as rs764333228, COSV63632155; called by muse, mutect2, varscan2
- KCNH4 | c.714C>G p.F238L | Missense Mutation (SNP) | VAF 12/264 reads (5%) | SIFT tolerated (0.16); PolyPhen benign (0.05); catalogued as COSV52918205; called by muse, mutect2
- KCNH6 | c.1088C>T p.T363I | Missense Mutation (SNP) | VAF 6/94 reads (6%) | SIFT deleterious (0.05); PolyPhen benign (0.281); catalogued as COSV100121115; called by muse, mutect2
- KPNA3 | c.838G>C p.V280L | Missense Mutation (SNP) | VAF 4/72 reads (6%) | SIFT deleterious (0); PolyPhen probably damaging (0.964); catalogued as COSV99904184; called by muse, mutect2
- LARP1 | c.718C>T p.R240* (on ENST00000518297 / NM_033551.3; = p.R163* on NM_015315.5 and 6 other RefSeq transcripts) | Nonsense Mutation (SNP) | VAF 23/66 reads (35%) | catalogued as COSV100303265; called by muse, mutect2, varscan2
- LCK | c.1344G>T p.E448D | Missense Mutation (SNP) | VAF 17/218 reads (8%) | SIFT tolerated (0.09); PolyPhen benign (0.103); catalogued as COSV100287758; called by muse, mutect2
- LHCGR | c.164C>T p.S55L | Missense Mutation (SNP) | VAF 16/73 reads (22%) | SIFT tolerated (0.82); PolyPhen probably damaging (0.997); catalogued as COSV99683808; called by muse, mutect2, varscan2
- LRGUK | c.1417G>A p.E473K | Missense Mutation (SNP) | VAF 22/84 reads (26%) | SIFT tolerated (0.53); PolyPhen benign (0.015); catalogued as COSV99604316, COSV99604367; called by muse, mutect2, varscan2
- LRRN3 | c.27T>A p.H9Q | Missense Mutation (SNP) | VAF 32/163 reads (20%) | SIFT tolerated (0.45); PolyPhen benign (0); catalogued as rs778831114, COSV100071260; called by muse, mutect2, varscan2
- M1AP | c.214C>A p.Q72K | Missense Mutation (SNP) | VAF 18/98 reads (18%) | SIFT deleterious (0.01); PolyPhen benign (0.392); catalogued as COSV99303754, COSV99304191; called by muse, mutect2, varscan2
- MAN2A1 | c.2028C>G p.F676L | Missense Mutation (SNP) | VAF 20/158 reads (13%) | SIFT tolerated (1); PolyPhen benign (0.001); catalogued as rs768163836, COSV99811326; called by muse, mutect2, varscan2
- MAP3K1 | c.1454C>A p.P485H | Missense Mutation (SNP) | VAF 17/64 reads (27%) | SIFT deleterious (0); PolyPhen probably damaging (0.956); catalogued as COSV101266917, COSV68122299; called by muse, mutect2, varscan2
- MATN1 | c.1311C>G p.F437L | Missense Mutation (SNP) | VAF 15/182 reads (8%) | SIFT deleterious (0); PolyPhen possibly damaging (0.478); catalogued as COSV101056340; called by muse, mutect2
- MC2R | c.310G>C p.D104H | Missense Mutation (SNP) | VAF 4/87 reads (5%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as COSV100563052, COSV59619684; called by muse, mutect2
- MS4A1 | c.514C>A p.P172T | Missense Mutation (SNP) | VAF 16/99 reads (16%) | SIFT tolerated (0.12); PolyPhen benign (0.34); catalogued as COSV100619342; called by muse, mutect2, varscan2
- MYH3 | c.737G>A p.G246D | Missense Mutation (SNP) | VAF 10/120 reads (8%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); catalogued as rs956286451, CM131715, COSV99878354; called by muse, mutect2
- NAP1L3 | c.1192G>A p.D398N | Missense Mutation (SNP) | VAF 3/33 reads (9%) | SIFT tolerated (0.1); PolyPhen possibly damaging (0.747); catalogued as COSV100220435; called by muse, mutect2
- NCKAP1 | c.903C>G p.F301L | Missense Mutation (SNP) | VAF 9/79 reads (11%) | SIFT tolerated (1); PolyPhen benign (0); catalogued as COSV100720324; called by muse, mutect2, varscan2
- NCOR1 | c.5219C>T p.P1740L | Missense Mutation (SNP) | VAF 14/188 reads (7%) | SIFT deleterious (0.02); PolyPhen benign (0.015); catalogued as COSV99250395; called by muse, mutect2
- NEIL1 | c.92C>G p.S31C | Missense Mutation (SNP) | VAF 7/81 reads (9%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.494); catalogued as COSV100748550; called by muse, mutect2
- NEK6 | c.890G>A p.G297E | Missense Mutation (SNP) | VAF 4/66 reads (6%) | SIFT tolerated (0.95); PolyPhen benign (0.001); catalogued as COSV52330542; called by muse, mutect2
- NEU3 | c.547G>T p.G183C | Missense Mutation (SNP) | VAF 18/204 reads (9%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV99579498; called by muse, mutect2
- NIFK | c.72G>C p.K24N | Missense Mutation (SNP) | VAF 14/152 reads (9%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.997); catalogued as rs938789584, COSV99035512; called by muse, mutect2
- NLRP9 | c.400G>C p.E134Q | Missense Mutation (SNP) | VAF 7/74 reads (9%) | SIFT tolerated (0.55); PolyPhen benign (0.01); catalogued as rs748136376, COSV60467071; called by muse, mutect2
- NPAS4 | c.499G>T p.V167L | Missense Mutation (SNP) | VAF 32/139 reads (23%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.826); catalogued as COSV100215057, COSV100215345, COSV60650174; called by muse, mutect2, varscan2
- OR2B11 | c.629T>G p.F210C | Missense Mutation (SNP) | VAF 7/58 reads (12%) | SIFT deleterious (0); PolyPhen possibly damaging (0.75); catalogued as COSV100276209; called by muse, mutect2, varscan2
- OR8I2 | c.398C>A p.S133* | Nonsense Mutation (SNP) | VAF 14/191 reads (7%) | catalogued as COSV100136117, COSV56171031; called by muse, mutect2
- PIK3AP1 | c.133C>A p.H45N | Missense Mutation (SNP) | VAF 6/76 reads (8%) | SIFT deleterious (0.01); PolyPhen benign (0.085); catalogued as COSV100225867; called by muse, mutect2
- PKD1 | c.10699G>T p.A3567S (on ENST00000262304 / NM_001009944.3; = p.A3566S on NM_000296.4) | Missense Mutation (SNP) | VAF 6/22 reads (27%) | SIFT tolerated (0.11); PolyPhen possibly damaging (0.744); catalogued as COSV99238312; called by muse, varscan2
- PLCZ1 | c.805G>T p.G269* | Nonsense Mutation (SNP) | VAF 25/154 reads (16%) | catalogued as COSV99856490; called by muse, mutect2, varscan2
- PPIG | c.1951A>T p.S651C | Missense Mutation (SNP) | VAF 4/40 reads (10%) | SIFT deleterious, low confidence (0.04); PolyPhen possibly damaging (0.908); catalogued as COSV99644640; called by muse, mutect2
- QSER1 | c.1482T>G p.I494M (on ENST00000399302; = p.I623M on NM_001076786.3) | Missense Mutation (SNP) | VAF 10/113 reads (9%) | SIFT tolerated (0.13); PolyPhen benign (0.293); catalogued as COSV101234874; called by muse, mutect2
- RAPGEFL1 | c.1214T>C p.V405A | Missense Mutation (SNP) | VAF 10/248 reads (4%) | SIFT tolerated (0.29); PolyPhen benign (0.007); catalogued as COSV99229028; called by muse, mutect2
- RASGRP2 | c.1753C>T p.R585* | Nonsense Mutation (SNP) | VAF 24/57 reads (42%) | catalogued as COSV62449081; called by muse, mutect2, varscan2
- RNF113A | c.88C>T p.R30C | Missense Mutation (SNP) | VAF 43/318 reads (14%) | SIFT deleterious (0.03); PolyPhen benign (0.005); catalogued as COSV65097406; called by muse, mutect2, varscan2
- RTL9 | c.3940G>A p.E1314K | Missense Mutation (SNP) | VAF 20/148 reads (14%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.998); catalogued as COSV101511708; called by muse, mutect2, varscan2
- SH2D4B | c.728C>G p.A243G | Missense Mutation (SNP) | VAF 7/20 reads (35%) | SIFT tolerated (0.26); PolyPhen benign (0.094); catalogued as COSV100213951; called by muse, mutect2, varscan2
- SHANK3 | c.3258C>A p.F1086L | Missense Mutation (SNP) | VAF 4/30 reads (13%) | SIFT tolerated (0.13); PolyPhen probably damaging (0.969); catalogued as COSV99437170; called by muse, mutect2, varscan2
- SLC35F3 | c.395G>T p.R132L (on ENST00000366617 / NM_001300845.1; = p.R201L on NM_173508.4) | Missense Mutation (SNP) | VAF 20/140 reads (14%) | SIFT tolerated (0.28); PolyPhen benign (0.268); catalogued as COSV100784797, COSV64018423; called by muse, mutect2, varscan2
- SLC44A1 | c.1207C>A p.Q403K | Missense Mutation (SNP) | VAF 21/169 reads (12%) | SIFT deleterious (0); PolyPhen possibly damaging (0.609); catalogued as COSV100570494; called by muse, mutect2, varscan2
- SLC4A5 | c.2434-1G>C p.X812_splice | Splice Site (SNP) | VAF 5/37 reads (14%) | catalogued as COSV100697744; called by muse, mutect2
- SLC5A11 | c.601A>G p.I201V | Missense Mutation (SNP) | VAF 123/386 reads (32%) | SIFT deleterious (0); PolyPhen probably damaging (0.961); catalogued as COSV100762822; called by muse, mutect2, varscan2
- SMG9 | c.53G>T p.R18L | Missense Mutation (SNP) | VAF 26/299 reads (9%) | SIFT deleterious, low confidence (0.01); PolyPhen probably damaging (0.982); catalogued as COSV99526771; called by muse, mutect2
- SPAG4 | c.8G>T p.R3L | Missense Mutation (SNP) | VAF 11/84 reads (13%) | SIFT deleterious, low confidence (0); PolyPhen benign (0.186); catalogued as COSV100958302; called by muse, mutect2, varscan2
- SPAG4 | c.149G>C p.R50T | Missense Mutation (SNP) | VAF 7/27 reads (26%) | SIFT deleterious, low confidence (0.01); PolyPhen benign (0.261); catalogued as COSV100958303; called by muse, mutect2, varscan2
- SPAST | c.1520C>G p.S507C | Missense Mutation (SNP) | VAF 5/39 reads (13%) | SIFT tolerated (0.08); PolyPhen benign (0.096); catalogued as COSV100188590; called by muse, mutect2
- SPDYE3 | c.1330C>T p.H444Y | Missense Mutation (SNP) | VAF 17/414 reads (4%) | SIFT deleterious (0.03); PolyPhen benign (0.376); catalogued as COSV100193689; called by muse, mutect2
- SPTBN1 | c.1595A>C p.K532T | Missense Mutation (SNP) | VAF 33/86 reads (38%) | SIFT deleterious (0.04); PolyPhen benign (0.292); catalogued as COSV100442816; called by muse, mutect2, varscan2
- STOML2 | c.524A>C p.Y175S | Missense Mutation (SNP) | VAF 98/236 reads (42%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); catalogued as COSV100493727; called by muse, mutect2, varscan2
- STOML3 | c.775G>T p.E259* | Nonsense Mutation (SNP) | VAF 12/30 reads (40%) | catalogued as COSV65510505, COSV65511300; called by muse, mutect2, varscan2
- TENT5D | c.631T>G p.F211V | Missense Mutation (SNP) | VAF 21/145 reads (14%) | SIFT deleterious (0.04); PolyPhen probably damaging (0.998); catalogued as COSV100382787; called by muse, mutect2, varscan2
- TMEM155 | c.41T>G p.L14R | Missense Mutation (SNP) | VAF 12/70 reads (17%) | SIFT deleterious, low confidence (0.02); PolyPhen possibly damaging (0.653); catalogued as rs1294733907, COSV100530069; called by muse, mutect2, varscan2
- TPTE | c.730G>A p.E244K (on ENST00000618007 / NM_199261.4; = p.E226K on NM_199259.4) | Missense Mutation (SNP) | VAF 28/498 reads (6%) | SIFT deleterious (0.02); PolyPhen benign (0.165); catalogued as rs755738282; called by muse, mutect2
- TRMT1L | c.2108G>C p.S703T | Missense Mutation (SNP) | VAF 30/164 reads (18%) | SIFT tolerated, low confidence (0.11); PolyPhen benign (0.006); catalogued as COSV100834648; called by muse, mutect2, varscan2
- TRPM2 | c.4313C>T p.A1438V | Missense Mutation (SNP) | VAF 13/199 reads (7%) | SIFT deleterious (0); PolyPhen probably damaging (0.921); catalogued as COSV100308948; called by muse, mutect2
- TSLP | c.240G>C p.Q80H | Missense Mutation (SNP) | VAF 10/268 reads (4%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.485); catalogued as COSV100789191; called by muse, mutect2
- TUBGCP2 | c.213A>T p.K71N | Missense Mutation (SNP) | VAF 6/75 reads (8%) | SIFT deleterious (0); PolyPhen probably damaging (0.992); catalogued as COSV99427884; called by muse, mutect2
- TULP4 | c.3301G>C p.E1101Q | Missense Mutation (SNP) | VAF 9/153 reads (6%) | SIFT deleterious, low confidence (0); PolyPhen possibly damaging (0.703); catalogued as COSV65572233; called by muse, mutect2
- UNC45B | c.1111G>A p.E371K | Missense Mutation (SNP) | VAF 15/446 reads (3%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.91); catalogued as COSV52101694; called by muse, mutect2
- XIRP2 | c.8543T>A p.L2848H (on ENST00000628543; = p.L3023H on NM_152381.6) | Missense Mutation (SNP) | VAF 14/129 reads (11%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV99743904; called by muse, mutect2, varscan2
- ZNF30 | c.607C>T p.P203S | Missense Mutation (SNP) | VAF 13/63 reads (21%) | SIFT deleterious (0.03); PolyPhen benign (0.351); catalogued as COSV100340600; called by muse, mutect2
- ZNF334 | c.1048G>A p.E350K | Missense Mutation (SNP) | VAF 26/263 reads (10%) | SIFT tolerated (0.29); PolyPhen benign (0.006); catalogued as rs1364509012, COSV61618421; called by muse, mutect2
- ZNF789 | c.926G>C p.G309A | Missense Mutation (SNP) | VAF 9/89 reads (10%) | SIFT deleterious (0); PolyPhen probably damaging (0.989); catalogued as COSV100507899; called by muse, mutect2
- ZNF827 | c.714G>T p.E238D | Missense Mutation (SNP) | VAF 19/73 reads (26%) | SIFT tolerated (0.69); PolyPhen benign (0.003); catalogued as COSV101061445; called by muse, mutect2, varscan2
- ADNP2 | c.382del p.H128Mfs*12 | Frame Shift Del (DEL) | VAF 18/89 reads (20%) | called by mutect2, pindel, varscan2
- GAGE1 | c.357G>C p.Q119H | Missense Mutation (SNP) | VAF 6/60 reads (10%) | SIFT deleterious (0.03); PolyPhen benign (0.012); called by muse, mutect2
- SUV39H1 | c.380C>G p.A127G | Missense Mutation (SNP) | VAF 4/40 reads (10%) | SIFT tolerated (0.07); PolyPhen benign (0.023); called by muse, mutect2
- ACE | c.1767C>T p.V589= | Silent (SNP) | VAF 6/46 reads (13%) | catalogued as rs140086153; called by muse, mutect2, varscan2
- ACTRT3 | c.1107A>G p.Q369= | Silent (SNP) | VAF 10/100 reads (10%) | catalogued as rs959424888, COSV100377499; called by muse, mutect2, varscan2
- ADAM30 | c.1020G>C p.L340= | Silent (SNP) | VAF 38/190 reads (20%) | catalogued as COSV101023894, COSV101023959; called by muse, mutect2, varscan2
- ADARB1 | c.2205C>T p.D735= (on ENST00000360697 / NM_001346687.2; = p.D695= on NM_001112.4) | Silent (SNP) | VAF 7/82 reads (9%) | catalogued as COSV100653895; called by muse, mutect2
- ALPP | c.783G>A p.A261= | Silent (SNP) | VAF 32/364 reads (9%) | catalogued as rs749165151; called by muse, mutect2
- ANKRD30A | c.4032T>C p.A1344= (on ENST00000611781; = p.A1288= on NM_052997.2) | Silent (SNP) | VAF 6/36 reads (17%) | catalogued as COSV100653696; called by muse, mutect2, varscan2
- ASMTL | c.1446C>T p.D482= | Silent (SNP) | VAF 8/116 reads (7%) | catalogued as COSV101187790; called by muse, mutect2
- DCST2 | c.399G>A p.Q133= | Silent (SNP) | VAF 3/42 reads (7%) | called by muse, mutect2
- DMD | c.4470A>G p.T1490= | Silent (SNP) | VAF 68/183 reads (37%) | catalogued as COSV100820227; called by muse, mutect2, varscan2
- FSTL4 | c.2445C>T p.L815= | Silent (SNP) | VAF 26/76 reads (34%) | catalogued as COSV99532927; called by muse, mutect2, varscan2
- GMPS | c.729C>T p.L243= | Silent (SNP) | VAF 11/114 reads (10%) | catalogued as COSV99903210; called by muse, mutect2
- HAO1 | c.267C>T p.D89= | Silent (SNP) | VAF 24/151 reads (16%) | catalogued as rs138052675; called by muse, mutect2, varscan2
- HCCS | c.732C>T p.D244= | Silent (SNP) | VAF 11/129 reads (9%) | catalogued as rs139955716, COSV58239376; called by muse, mutect2
- HS3ST5 | c.291G>C p.G97= | Silent (SNP) | VAF 47/113 reads (42%) | catalogued as rs1331682754, COSV100451027, COSV57140846; called by muse, mutect2, varscan2
- LPIN2 | c.1425G>A p.G475= | Silent (SNP) | VAF 4/60 reads (7%) | called by muse, mutect2
- MTMR10 | c.1788C>T p.I596= | Silent (SNP) | VAF 14/214 reads (7%) | catalogued as COSV100076159; called by muse, mutect2
- MUC4 | c.13773C>T p.D4591= (on ENST00000463781 / NM_018406.7; = p.D355= on NM_004532.6) | Silent (SNP) | VAF 6/86 reads (7%) | catalogued as COSV100205087, COSV57769200; called by muse, mutect2
- NCOR2 | c.2673C>G p.L891= | Silent (SNP) | VAF 11/152 reads (7%) | catalogued as COSV100657448; called by muse, mutect2
- OR4C13 | c.414T>A p.V138= | Silent (SNP) | VAF 10/142 reads (7%) | catalogued as COSV101634200; called by muse, mutect2
- PLB1 | c.3915C>T p.F1305= | Silent (SNP) | VAF 6/118 reads (5%) | catalogued as COSV100578946, COSV59835495; called by muse, mutect2
- POMGNT2 | c.1476G>A p.A492= | Silent (SNP) | VAF 18/98 reads (18%) | catalogued as rs371889758; called by muse, mutect2, varscan2
- RPL13 | c.339C>T p.N113= | Silent (SNP) | VAF 16/49 reads (33%) | catalogued as COSV99245023; called by muse, mutect2, varscan2
- SCN4A | c.2871C>T p.L957= | Silent (SNP) | VAF 6/36 reads (17%) | catalogued as COSV101438518; called by muse, mutect2, varscan2
- SLC22A1 | c.1164G>A p.P388= | Silent (SNP) | VAF 11/91 reads (12%) | catalogued as rs142714915; called by muse, mutect2, varscan2
- SLC7A4 | c.1203C>G p.A401= | Silent (SNP) | VAF 9/53 reads (17%) | catalogued as COSV100298739; called by muse, mutect2, varscan2
- SMARCA1 | c.660T>A p.A220= | Silent (SNP) | VAF 34/516 reads (7%) | catalogued as COSV100946579; called by muse, mutect2
- STRBP | c.954C>G p.A318= | Silent (SNP) | VAF 33/138 reads (24%) | catalogued as COSV100724223; called by muse, mutect2, varscan2
- TAC1 | c.249G>C p.L83= | Silent (SNP) | VAF 5/35 reads (14%) | catalogued as rs1410461298, COSV100071145; called by muse, mutect2
- TAF1C | c.771G>A p.G257= | Silent (SNP) | VAF 13/104 reads (13%) | catalogued as rs1331668296, COSV58985824; called by muse, mutect2, varscan2
- TBXT | c.1143G>T p.A381= | Silent (SNP) | VAF 12/107 reads (11%) | catalogued as rs776170985, COSV99752591; called by muse, mutect2, varscan2
- TKTL2 | c.153C>G p.V51= | Silent (SNP) | VAF 6/41 reads (15%) | catalogued as COSV99761472; called by muse, mutect2, varscan2
- WDR83 | c.228C>T p.S76= | Silent (SNP) | VAF 11/202 reads (5%) | catalogued as COSV99663899; called by muse, mutect2
- WSB1 | c.150T>C p.A50= | Silent (SNP) | VAF 49/358 reads (14%) | catalogued as rs1430267514, COSV99286040; called by muse, mutect2, varscan2
- ZNF813 | c.1068G>A p.K356= | Silent (SNP) | VAF 35/186 reads (19%) | catalogued as COSV67176551; called by muse, mutect2, varscan2
- ARL10 | c.386-842C>A | Intron (SNP) | VAF 30/176 reads (17%) | catalogued as COSV100119077; called by muse, mutect2, varscan2
- ELK1 | chrX:47650499 C>A | 5'Flank (SNP) | VAF 28/145 reads (19%) | catalogued as COSV99902168; called by muse, mutect2, varscan2
- NXF5 | n.1299A>G | RNA (SNP) | VAF 27/193 reads (14%) | catalogued as rs776316538, COSV99534435; called by muse, mutect2, varscan2
- RTL1 | c.-148-4452G>C | Intron (SNP) | VAF 18/114 reads (16%) | catalogued as rs544532611; called by muse, mutect2, varscan2
- SLCO1B3-SLCO1B7 | c.1866-44410C>T | Intron (SNP) | VAF 16/121 reads (13%) | catalogued as rs773510134, COSV101045020, COSV67442084; called by muse, mutect2, varscan2
- SNORD116-5 | n.44T>G | RNA (SNP) | VAF 22/171 reads (13%) | called by muse, mutect2, varscan2
